Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040024-09A.2 (aliquot TARGET-15-SJMPAL040024-09A.2-01D) from TARGET case TARGET-15-SJMPAL040024, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.0 years (366 days).
Specimen TARGET-15-SJMPAL040024-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e475f1ed-89f3-47c7-9e35-137c8fc0f7e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040024-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040024-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7c0c8e7-1400-4879-9236-ad65273090d0

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MICAL2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396469560, COSV56327169; called by muse, mutect2
- PLS3 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99171651; called by muse, mutect2, varscan2
- PREX1 | c.1989G>T p.Q663H | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- SRCAP | c.6889del p.R2297Gfs*10 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | called by mutect2, pindel, varscan2
